Surgical pathology report (de-identified scan), TCGA case TCGA-27-2528, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-2528-01A (Primary Tumor).

[REDACTED]

[REDACTED]

[REDACTED] TCGA-27-2528

Ref. Number

[REDACTED]

Gender

[REDACTED]

Birth date

[REDACTED]

Tumor site

Right temporo-mesial

Histological diagnosis

Glioblastoma multiforme

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file eb6f37d5-a91b-471e-9e7c-36714ae9f432 (TCGA-27-2528.08B4C97D-4213-4897-BF40-0327EEFE8385.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).